Gene-level copy-number profile of tumor specimen ALCH-ADO4-TTP1-B from ALCHEMIST case ALCH-ADO4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.2 years (24,918 days).
Specimen ALCH-ADO4-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5eec0a8c-9def-4b63-b24f-c28f7b483649.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADO4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/095dfa72-5f3e-43fa-afcf-837c27116293

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 3,310; copy number 2: 40,022; copy number 3: 10,998; copy number 4: 3,356; copy number 5: 1,164; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,200,797–20,225,433, 1 gene: SDC1.
- chr3:50,558,025–50,571,027, 1 gene (within-gene range 0–2): C3orf18.
- chr8:12,115,767–12,177,550, 6 genes: FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr9:61,190,003–61,627,683, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D.
- chr10:1,526,637–1,556,984, 1 gene (within-gene range 0–2): ADARB2-AS1.
- chr10:48,443,836–48,445,820, 1 gene: AC016397.2.
- chr11:3,217,944–3,232,838, 4 genes: MRGPRG, MRGPRG-AS1, MRGPRE, AC109309.1.
- chr12:111,304,142–111,304,209, 1 gene (within-gene range 0–2): MIR6760.
- chr12:125,056,359–125,143,333, 3 genes (within-gene range 0–2): AC122688.1, AACS, AC122688.3.
- chr16:1,221,651–1,230,184, 3 genes (within-gene range 0–2): TPSG1, AC120498.10, TPSB2.
- chr16:1,984,193–1,994,275, 3 genes: GFER, AC005606.2, SYNGR3.
- chr17:16,415,571–16,492,193, 8 genes (within-gene range 0–1): TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr19:8,581,160–8,582,715, 1 gene (within-gene range 0–1): AC130469.1.
- chr19:42,752,686–43,171,515, 11 genes (within-gene range 0–2): PSG8, CEACAMP6, PSG8-AS1, PSG10P, PSG1, PSG6, PSG7, CEACAMP7, AC004784.1, PSG11, CEACAMP8.
- chr20:30,214,765–30,214,976, 1 gene: CFTRP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,165 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:87,379,880–87,380,767, 1 gene, copy number 5: AC068279.1.
- chr2:87,629,755–87,629,834, 1 gene, copy number 5: MIR4435-1.
- chr7:105,605,067–151,520,120, 891 genes, copy number 5 (broad region; genes not listed).
- chr7:155,644,451–155,781,485, 1 gene, copy number 5 (within-gene range 4–5): RBM33.
- chr11:83,455,012–96,514,748, 265 genes, copy number 5 (broad region; genes not listed).
- chr17:18,432,051–18,494,945, 6 genes, copy number 5–8: KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C.

Autosomal genes at a single copy (total copy number 1): 2,762. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
